Gene-level copy-number profile of specimen HCM-SANG-0518-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-0518-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0518-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 93d8d546-ffa6-4f74-a65f-a370457a368e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0518-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/0fec6430-cb5a-436a-9ec8-818680d68991

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 427; copy number 1: 314; copy number 2: 9,371; copy number 3: 19,165; copy number 4: 27,853; copy number 5: 1,715; copy number 6: 36; copy number 7: 23; copy number 8: 3; copy number 10: 2; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:41,573,156–41,573,606, 2 genes, copy number 10: AL591926.3, SNORA70.
- chr9:64,878,790–64,889,063, 2 genes, copy number 11: AC125634.1, RNU6-1293P.

Autosomal genes at a single copy (total copy number 1): 275. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
